Somatic mutation profile of tumor specimen C3N-02754-01 (aliquot CPT0183850036) from CPTAC case C3N-02754, project CPTAC-3 (Pancreas — Ductal and Lobular Neoplasms). Sex at birth: male; Vital status: Dead; Primary diagnosis: Infiltrating duct carcinoma, NOS; Tissue or organ of origin: Pancreas, NOS; AJCC pathologic stage: Stage III; Tumor grade: G1; Age at diagnosis: 62.0 years (22,651 days).
Specimen C3N-02754-01: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Biospecimen anatomic site: Pancreas; Preservation method: Snap Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 63b5609a-da4d-46fc-b180-9974d99f6467.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen C3N-02754-71 (Blood Derived Normal), aliquot CPT0183910002; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/9cbbccac-b563-42b0-bc8f-81a6d960fa52

The open-access MAF lists 16 somatic variants for this specimen: 14 protein-altering or splice-affecting, 2 silent.
By variant classification: Missense Mutation 11, Silent 2, Nonsense Mutation 2, Frame Shift Del 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- STK11 | c.647C>T p.S216F | Missense Mutation (SNP) | VAF 18/262 reads (7%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as rs1057520017, COSV58821219; ClinVar: likely pathogenic; called by muse, mutect2
- DCHS2 | c.467G>A p.R156H | Missense Mutation (SNP) | VAF 17/555 reads (3%) | SIFT tolerated (0.2); PolyPhen benign (0.031); catalogued as rs1202050640; called by muse, mutect2
- EPHA6 | c.884G>A p.R295H | Missense Mutation (SNP) | VAF 8/66 reads (12%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.997); catalogued as rs773107512, COSV67559447, COSV67572371; called by muse, mutect2
- FPR1 | c.235C>T p.P79S | Missense Mutation (SNP) | VAF 20/196 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs754232242, COSV59051992; called by muse, mutect2, varscan2
- SLCO3A1 | c.512C>T p.T171M | Missense Mutation (SNP) | VAF 26/566 reads (5%) | SIFT tolerated (0.1); PolyPhen benign (0.166); catalogued as rs565500840; called by muse, mutect2
- SOGA1 | c.4943C>T p.S1648F | Missense Mutation (SNP) | VAF 13/199 reads (7%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.75); catalogued as COSV99412465; called by muse, mutect2
- VEGFB | c.73C>T p.Q25* | Nonsense Mutation (SNP) | VAF 10/244 reads (4%) | catalogued as COSV100374919; called by muse, mutect2
- CCDC168 | c.14191T>A p.S4731T | Missense Mutation (SNP) | VAF 17/242 reads (7%) | SIFT tolerated (0.25); PolyPhen possibly damaging (0.725); called by muse, mutect2
- KIAA1109 | c.8510T>C p.V2837A | Missense Mutation (SNP) | VAF 12/226 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.97); called by muse, mutect2
- MANBAL | c.246G>T p.K82N | Missense Mutation (SNP) | VAF 9/178 reads (5%) | SIFT deleterious (0.05); PolyPhen probably damaging (0.995); called by muse, mutect2
- PTPRQ | c.1793C>T p.P598L (on ENST00000616559; = p.P556L on NM_001145026.2) | Missense Mutation (SNP) | VAF 22/403 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (1); called by muse, mutect2
- RBM10 | c.1957A>T p.K653* | Nonsense Mutation (SNP) | VAF 28/296 reads (9%) | called by muse, mutect2
- SHC4 | c.1648G>C p.E550Q | Missense Mutation (SNP) | VAF 25/423 reads (6%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.889); called by muse, mutect2
- SPRYD4 | c.112del p.T38Pfs*29 | Frame Shift Del (DEL) | VAF 5/40 reads (13%) | called by mutect2, pindel
- CYTH4 | c.183G>A p.K61= | Silent (SNP) | VAF 14/217 reads (6%) | catalogued as COSV50633779; called by muse, mutect2
- DOCK2 | c.4596C>T p.N1532= | Silent (SNP) | VAF 11/169 reads (7%) | catalogued as rs372927020; ClinVar: likely benign; called by muse, mutect2
